Gene-level copy-number profile of tumor specimen ALCH-B4C4-TTP1-B from ALCHEMIST case ALCH-B4C4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.6 years (27,968 days).
Specimen ALCH-B4C4-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 522c9bff-ea17-40b3-9ef2-18487d99a9df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4C4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/22f550e2-6dc1-420f-a900-aac87aab7332

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 2,099; copy number 2: 55,740; copy number 3: 430; copy number 4: 45; copy number 5: 1; copy number 17: 2; copy number 19: 3.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,479,827–232,487,834, 1 gene: ECEL1.
- chr9:93,955,597–93,959,140, 1 gene: BARX1-DT.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr9:137,877,782–138,253,217, 7 genes (within-gene range 0–2): CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr11:63,985,853–64,166,113, 6 genes (within-gene range 0–2): OTUB1, MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1.
- chr11:85,452,282–85,510,044, 2 genes (within-gene range 0–2): AP003035.1, RNU6-1292P.
- chr13:114,107,569–114,108,820, 1 gene (within-gene range 0–1): RASA3-IT1.
- chr14:99,481,169–99,535,044, 1 gene (within-gene range 0–2): CCNK.
- chr14:99,512,501–99,513,576, 1 gene (within-gene range 0–2): AL110504.1.
- chr15:25,184,306–25,243,695, 33 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr15:78,749,833–78,811,464, 3 genes (within-gene range 0–2): AC022748.3, AC022748.1, ADAMTS7.
- chr16:89,818,179–89,938,761, 7 genes: SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr20:37,444,733–37,445,534, 1 gene: RPL7AP14.
- chr22:18,605,355–18,615,900, 4 genes: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP.
- chr22:29,705,256–29,770,413, 7 genes: AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,340,145–18,391,105, 3 genes, copy number 19: GGTLC5P, FAM230J, AC011718.1.
- chr22:18,623,339–18,653,617, 3 genes, copy number 5–17: SUSD2P2, CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 453. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
